Gene-level copy-number profile of tumor specimen TCGA-Z6-A8JD-01A from TCGA case TCGA-Z6-A8JD, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 53.5 years (19,523 days).
Specimen TCGA-Z6-A8JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.c0426dfa-8a8e-4fe5-89c0-9d7a8c7dee1f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z6-A8JD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0702a78-0700-48eb-a1e6-d7337cf1914a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 13,333; copy number 2: 39,842; copy number 3: 5,706; copy number 4: 528; copy number 5: 177; copy number 6: 20; copy number 7: 32; copy number 10: 127.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z6-A8JD-01A-11D-A36I-01): tumor purity 0.23, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:235,773,855–235,783,387, 1 gene: AC064874.1.
- chr4:159,103,013–159,360,174, 1 gene (within-gene range 0–2): RAPGEF2.
- chr15:46,317,393–49,046,447, 48 genes: AC091074.3, MTND5P40, AC091074.1, AC091074.2, AC012405.1, RNU6-1014P, AC073941.1, RN7SKP101, AC073941.2, AC066615.1, SEMA6D, RN7SKP139, AC084882.1, AC023905.1, AC009558.1, AC009558.2, AC012050.1, AC044787.1, LINC01491, AC092078.2, AC092078.1, AC092078.3, SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4, CEP152, AC084757.1, AC084757.2, AC012379.1, AC012379.2, SHC4, EID1, AC091073.1, KRT8P24, SECISBP2L, Y_RNA, RN7SL577P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 356 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:118,184,144–118,513,830, 3 genes, copy number 6: LSM8, ANKRD7, AC002529.1.
- chr8:123,262,843–131,144,948, 128 genes, copy number 5–7 (broad region; genes not listed).
- chr12:25,959,029–26,079,892, 1 gene, copy number 6 (within-gene range 3–6): RASSF8.
- chr19:34,788,527–36,916,291, 143 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr22:20,318,119–21,624,034, 81 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
